Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OF, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OF-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 1
SEX: M

PROCEDURE: SPHS

Patient with long-standing history of gastroesophageal reflux diagnosed with
barrett's esophagus in [REDACTED] had E-scope with biopsy of
esophageal mass, path revealed invasive adenocarcinoma arising in barrett's
mucosa. Operative Procedure/Tissue Submitted: THE(1) distal esophagus and
proximal stomach, stitch marks tumor [REDACTED] barrett's adjacent to tumor
[REDACTED] paraesophageal lymph node [REDACTED] final proximal esophageal margin

1ED-0-3

adenocarcinoma, NOS 8140/3
Site: distal third esophagus C15.5
lw
10/9/12

PROCEDURE: SPGD

VERIFIED BY: [REDACTED]

1. "Distal esophagus and proximal stomach. Stitch marks tumor." Received in
formalin in a small container is a distal esophagectomy/proximal gastrectomy,
consisting of esophagus (7.9 cm long), stomach (4.5 x 4.7 cm), and
paraesophageal/perigastric soft tissue. The distal esophagus shows a firm,
exophytic, brown-tan mass, 3.3 cm in length x 1.3 cm, 3.2 cm from the proximal
esophageal margin, 5.8 cm from the distal margin, 1.7 cm from the
gastroesophageal junction. Deep inked green. NOTE: A full-thickness portion
of the esophagus appears to have been procured adjacent to the tumor marked by
stitch (3.3 cm from proximal margin, 1.0 cm from gastroesophageal junction).
Due to pre-grossing manipulation, there was apparent separation between mucosa
and underlying muscularis propria, making full thickness sections difficult to
obtain and exact reapproximation impossible. The mass is 0.7 cm from the
possible area of procurement. The gastroesophageal junction shows a 0.5 cm
area of hyperemia. Otherwise, the gastric and esophageal mucosa is
unremarkable. Multiple lymph node candidates identified. Photographs taken
for reference.

1A-C. Mass, entirely submitted.

1D. Strip of mucosa adjacent to possible procurement defect and mass.

1E-F. Additional tissue near possible procurement defect.

1G-H. Sections of muscularis underlying possible procurement defect.

1I. Gastroesophageal junction erosion and additional sections of
gastroesophageal junction.

1J. One lymph node candidate, sectioned.

1K-M. Seven lymph node candidates each.

2. "Barrett's adjacent to tumor" Received in formalin in a small container is
a 2.5 x 2.0 x 0.3 cm fragment of tan tissue, possibly partially surfaced by
brown-tan, granular mucosa without gross lesion. Sectioned and submitted in
cassette 2A.

3. "Paraesophageal lymph node" Received in formalin in a small container is a
black-brown bit, 0.4 cm.

4. "Final proximal esophageal margin" Received in formalin in a small
container is a 0.5 cm long x 2.5 cm in diameter, segment of esophagus, stapled
at one end. Staple line shaved and retained.

Source: NCI Genomic Data Commons file f2632226-c797-42fb-9d64-1004fdd39be7 (TCGA-L5-A4OF.01722316-B201-428E-96E1-D6A4B2D9053E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).